Somatic mutation profile of tumor specimen 0DWRMU from CCDI case PBCNNH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Sympathetic paraganglioma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 22.9 years (8,373 days).
Specimen 0DWRMU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93433a70-5e1a-4fb7-a75a-6a73f6620614.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWRMY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84dda039-6bd4-4b03-ac6d-02da855eb99a

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Splice Site 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEDD | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 83/965 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs767805103; called by muse, mutect2
- EPAS1 | c.1586T>C p.L529P | Missense Mutation (SNP) | VAF 525/1029 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55383840, COSV55385339; called by muse, mutect2, varscan2
- GLO1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 22/727 reads (3%) | called by muse, mutect2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 22/714 reads (3%) | called by muse, mutect2
- HDAC6 | c.3475G>A p.G1159S | Missense Mutation (SNP) | VAF 81/390 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- HDGFL1 | c.231G>A p.A77= | Silent (SNP) | VAF 30/868 reads (3%) | catalogued as rs1467805163, COSV100014478; called by muse, mutect2
